MMRF case MMRF_1108 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3a04411e-31eb-4fea-bd93-73deb4e6958f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 85 years; Vital status: Dead; Days to death: 1,616 days (4.4 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 85.3 years (31,169 days); ISS stage: III; Days to last known disease status: 1,616 days (4.4 years); Days to last follow up: 1,616 days (4.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 44 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 4 days; Days to treatment end: 40 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 40 days; Days to treatment end: 194 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 306 days; Days to treatment end: 1,034 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,048 days (2.9 years); Days to treatment end: 1,174 days (3.2 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,083 days (3.0 years); Days to treatment end: 1,230 days (3.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,188 days (3.3 years); Days to treatment end: 1,314 days (3.6 years).
   Treatment given: Therapeutic agents: Dexamethasone + Ixazomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,433 days (3.9 years); Days to treatment end: 1,433 days (3.9 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,616.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 165 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.15 mg/dL; Immunoglobulin G 62.8 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 7 µg/mL; Hemoglobin 5.64 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 194 ×10⁹/L; Albumin 37 g/L; Total Protein 10.5 g/dL.
- Day 90 (ECOG 1): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 34.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 29.9 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.66 g/L; Beta 2 Microglobulin 8.8 µg/mL; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 5.8 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.5 mmol/L; Albumin 36 g/L; Total Protein 8.8 g/dL; Glucose 6.33 mmol/L.
- Day 187 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 6.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.73 mg/dL; Immunoglobulin G 9.54 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 1.08 g/L; Beta 2 Microglobulin 7.3 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 3.4 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 6.4 g/dL; Glucose 7.15 mmol/L.
- Day 264 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.6 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 1.17 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.71 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 4.4 mmol/L.
- Day 362 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.21 mg/dL; Immunoglobulin G 8.93 g/L; Immunoglobulin A 1.07 g/L; Immunoglobulin M 0.76 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.14 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.45 mmol/L.
- Day 446 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 5.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.61 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.83 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.93 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 5.28 mmol/L.
- Day 532 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.73 mg/dL; Immunoglobulin G 9.27 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.8 g/L; Beta 2 Microglobulin 1 µg/mL; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 3.3 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 4.46 mmol/L.
- Day 614 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.76 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.99 g/L; Beta 2 Microglobulin 4.4 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.56 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 5.61 mmol/L.
- Day 768 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 8.73 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.86 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.66 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.94 mmol/L.
- Day 796 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 9.85 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.82 g/L; Beta 2 Microglobulin 4.7 µg/mL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.07 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 5.06 mmol/L.
- Day 922 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 4.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.59 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.83 g/L; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.19 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 5.5 mmol/L.
- Day 978: Serum Free Immunoglobulin Light Chain, Kappa 6.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.76 g/L; Beta 2 Microglobulin 1 µg/mL; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.4 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.34 mmol/L.
- Day 1,083: M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Immunoglobulin G 18.4 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 1.04 g/L; Beta 2 Microglobulin 3.7 µg/mL; Lactate Dehydrogenase 3.82 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 15 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 8.36 mmol/L.
- Day 1,174: Serum Free Immunoglobulin Light Chain, Kappa 7.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.88 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 1.13 g/L; Beta 2 Microglobulin 5.9 µg/mL; Lactate Dehydrogenase 3.53 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 3.9 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 6.44 mmol/L.
- Day 1,272: Serum Free Immunoglobulin Light Chain, Kappa 8.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.81 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 7.59 mmol/L.
- Day 1,433: Serum Free Immunoglobulin Light Chain, Kappa 21.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Immunoglobulin G 21.1 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.73 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7.7 g/dL; Glucose 5.61 mmol/L.
- Day 1,517: M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 19.6 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 6.9 µg/mL; Hemoglobin 6.57 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 76 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.48 mmol/L; Albumin 39 g/L; Total Protein 7.8 g/dL; Glucose 6.49 mmol/L.

Other clinical attributes
- Day 1: Weight: 60 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1108_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1108_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
